Somatic mutation profile of tumor specimen TCGA-AR-A1AS-01A (aliquot TCGA-AR-A1AS-01A-11D-A12Q-09) from TCGA case TCGA-AR-A1AS, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 54.8 years (20,028 days).
Specimen TCGA-AR-A1AS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42ea4d31-b0a2-4575-9801-8a71f4178a05.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A1AS-10A (Blood Derived Normal), aliquot TCGA-AR-A1AS-10A-01D-A12Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e0e31082-4736-4917-a72b-9bf455239984

The open-access MAF lists 42 somatic variants for this specimen: 30 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 24, Silent 12, Nonsense Mutation 3, Nonstop Mutation 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 32/109 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1634A>C p.E545A | Missense Mutation (SNP) | VAF 43/85 reads (51%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs121913274, CM130273, COSV55873209, COSV55873220, COSV55892885; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 20/39 reads (51%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ATP10B | c.650G>A p.C217Y | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs751974766, COSV58777633; called by muse, varscan2
- BCL11A | c.2329G>A p.V777M (on ENST00000335712 / NM_001365609.1; = p.V811M on NM_022893.4) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59623787; called by muse, mutect2, varscan2
- CARD14 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 23/50 reads (46%) | catalogued as rs377316099; called by muse, mutect2, varscan2
- CNGA4 | c.770G>A p.G257D | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV66004935; called by muse, mutect2, varscan2
- EIF4A3 | c.998C>G p.S333C | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV53919504; called by muse, mutect2, varscan2
- FANCI | c.615G>A p.M205I | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV100167620; called by muse, mutect2
- GIMAP4 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV55431017, COSV55431055; called by muse, mutect2, varscan2
- GLRX2 | c.494G>C p.*165Sext*4 (on ENST00000367439 / NM_197962.3; = p.*166Sext*4 on NM_016066.4 and 1 other RefSeq transcript) | Nonstop Mutation (SNP) | VAF 21/119 reads (18%) | catalogued as COSV66471625; called by muse, mutect2, varscan2
- GOLPH3 | c.255A>G p.I85M | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54059621, COSV54060568; called by muse, mutect2, varscan2
- HMGN5 | c.329A>C p.E110A | Missense Mutation (SNP) | VAF 80/195 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV63916237; called by muse, mutect2, varscan2
- LARP6 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs771366776, COSV54578749; called by muse, mutect2, varscan2
- LCAT | c.94T>A p.F32I | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50452057; called by muse, mutect2, varscan2
- MAP2K4 | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100796114, COSV100796600, COSV62254757; called by muse, mutect2, varscan2
- MAPK4 | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.79); catalogued as rs764772500, COSV68541047, COSV68543116; called by muse, mutect2, varscan2
- PLXNA4 | c.4475G>A p.R1492H | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58103431; called by muse, mutect2, varscan2
- RBM6 | c.2036A>G p.Y679C | Missense Mutation (SNP) | VAF 47/89 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV56479516; called by muse, mutect2, varscan2
- RYR2 | c.1682G>T p.R561I | Missense Mutation (SNP) | VAF 55/262 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63659356; called by muse, mutect2, varscan2
- SPRR2B | c.96C>A p.C32* | Nonsense Mutation (SNP) | VAF 47/222 reads (21%) | catalogued as rs371615728, COSV58796772; called by muse, mutect2, varscan2
- SRGAP2 | c.1526G>A p.S509N (on ENST00000624873 / NM_001170637.4; = p.S510N on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99832588; called by muse, mutect2
- TMEM185A | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.031); catalogued as rs1347457827; called by muse, mutect2, varscan2
- TTN | c.78115G>A p.D26039N (on ENST00000591111; = p.D18615N on NM_003319.4) | Missense Mutation (SNP) | VAF 24/56 reads (43%) | PolyPhen possibly damaging (0.558); catalogued as COSV59874157; called by muse, mutect2, varscan2
- TXNDC2 | c.1213C>T p.P405S (on ENST00000306084 / NM_001098529.2; = p.P338S on NM_032243.6) | Missense Mutation (SNP) | VAF 70/181 reads (39%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.946); catalogued as rs764536122, COSV60151694; called by muse, mutect2, varscan2
- WRAP73 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV54559910; called by mutect2, varscan2
- ZC3H11A | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.331); catalogued as COSV59744394; called by muse, mutect2, varscan2
- COL6A3 | c.9228_9229+4del p.X3076_splice | Splice Site (DEL) | VAF 8/35 reads (23%) | called by mutect2, pindel, varscan2
- MYOF | c.2006_2009del p.T669Ifs*2 | Frame Shift Del (DEL) | VAF 44/130 reads (34%) | called by pindel, varscan2
- SPTA1 | c.5392_5404delinsT p.V1798_E1802delins* | Nonsense Mutation (DEL) | VAF 27/118 reads (23%) | called by pindel, varscan2*
- EPHB6 | c.3042G>A p.L1014= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV63890311; called by muse, mutect2, varscan2
- EYA2 | c.1110G>A p.V370= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as COSV57937755; called by muse, mutect2, varscan2
- FUOM | c.99G>A p.L33= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV53369162; called by muse, mutect2, varscan2
- GATA3 | c.414C>G p.S138= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV60515292; called by muse, mutect2, varscan2
- IRAK3 | c.891A>C p.A297= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as COSV54159159; called by muse, mutect2, varscan2
- LRFN5 | c.1929G>A p.Q643= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as COSV53241918; called by muse, mutect2, varscan2
- MUC15 | c.882G>A p.V294= | Silent (SNP) | VAF 50/139 reads (36%) | catalogued as rs1363013294, COSV55552666; called by muse, mutect2, varscan2
- PCDHA4 | c.340C>T p.L114= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV63538665; called by muse, mutect2, varscan2
- POM121L12 | c.267G>A p.P89= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs772385441, COSV101374858, COSV68692323; called by muse, mutect2
- SLC35F3 | c.954A>T p.V318= (on ENST00000366617 / NM_001300845.1; = p.V387= on NM_173508.4) | Silent (SNP) | VAF 10/182 reads (5%) | catalogued as COSV100784738; called by muse, mutect2
- SPATA46 | c.729C>T p.F243= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV62631863; called by muse, mutect2
- TOMM40 | c.1080C>T p.I360= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as rs894059862, COSV52984947; called by muse, mutect2, varscan2
